Surgical pathology report (de-identified scan), TCGA case TCGA-QR-A6ZZ, project TCGA-PCPG (Pheochromocytoma and Paraganglioma), tissue source site National Institutes of Health, specimen TCGA-QR-A6ZZ-01A (Primary Tumor).

[page 1 of 2]
Surgical Pathology	Final Results
Surgical Pathology	Final

CASE NUMBER:

DIAGNOSIS: Adrenal gland, right, partial adrenalectomy:
Pheochromocytoma, see note.

NOTE: The tumor cells are positive for Synaptophysin, chromogranin and S100.

Immunoperoxidase and in-situ hybridization tests performed here and used for diagnosis were developed and their performance characteristics determined by the Laboratory of Pathology. They have not been cleared or approved by the U.S. Food and Drug Administration. The FDA has also determined that such clearance or approval is not necessary. This laboratory is certified under the Clinical Laboratory Improvement Amendments of 1988 (CLIA) as qualified to perform high complexity clinical laboratory testing.

CLINICAL INFORMATION: Brief Clinical History: pheochromocytoma
Specimen Taken For Protocol:
01 - Yes Allocate Order to Protocol:

PROCEDURE: Pre-Operative Diagnosis: pheochromocytoma Post-Operative
Diagnosis:
pheochromocytoma Operative Findings: right adrenal mass

SPECIMENS SUBMITTED: 1. ADRENAL GLAND, RIGHT

GROSS DESCRIPTION: Received fresh in a container labeled with the patient's name, medical record number, and further specified as "right adrenal gland" is a portion of adrenal gland with attached fat weighing 5 grams, measuring 4.0 x 2.4 x 1.5 cm. The adrenal gland itself is 3.6 x 2.1 x 1.5 cm. The exterior surface is inked black. There is one palpable nodule at one end measuring 2.1 x 1.8 x 1.5 cm. The nodule is well-circumscribed and medullary in location and surrounded by cortex. Cut surface shows orange-red in color and soft consistency. Gross photographs are taken. Approximately 50% of tissue from the center of the nodule, 40% of normal adrenal gland are procured for Lab. Approximately 0.5 x 0.5 x 0.5 cm of normal periadrenal fat is procured for. The remainder of the specimen is placed into formalin and submitted to Pathology for permanent processing. The procurement was performed by at
Received in Surgical Pathology is a specimen matching the above description in a formalin-filled container. It is sectioned and submitted as follows:

- the nodule
- more parts of the nodule
- parts of normal compressed adrenal gland

[page 2 of 2]
Surgical Pathology	Final Results
---------------------------	----------------------

Gross Description dictated by _____ on _____

No consultants

Accessioned:

Final Report Signed Out:

<Resident Signature>

<Sign Out Dr. Signature>

Date Report Signed:

Prior hemangioblastoma

Criteria	7/25/13	Yes	No
Prior Malignant History	Brain	✓	
Dr. +/- Synchronous Primary Noted			✓

Requested By:

Do not file in Medical Record

Source: NCI Genomic Data Commons file 5166eecf-c3b3-4a22-82e4-a69b2ec01ad3 (TCGA-QR-A6ZZ.01D46DC6-3444-49D7-BB42-450F3F072C06.PDF), Data Release 46.0 - August 10, 2026; text from the OCR (chandra-v1.5.0).